Somatic mutation profile of tumor specimen MMRF_1772_1_BM_CD138pos (aliquot MMRF_1772_1_BM_CD138pos_T1_KBS5U_L06503) from MMRF case MMRF_1772, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 48.8 years (17,827 days).
Specimen MMRF_1772_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40691593-20be-45e4-a9a0-022f4ec0af92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1772_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1772_1_PB_CD3pos_C4_KBS5U_L06507; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f96f632b-432b-4bcf-aa5f-5defe5bfb11b

The open-access MAF lists 186 somatic variants for this specimen: 66 protein-altering or splice-affecting, 33 silent, 87 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, 3'UTR 50, Silent 33, Intron 20, 5'UTR 6, RNA 4, 3'Flank 4, 5'Flank 3, Nonsense Mutation 3, Splice Region 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL10 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65354078; called by muse, mutect2
- BTBD10 | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.332); catalogued as rs1183944594; called by muse, mutect2
- COL5A1 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 25/420 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs763456705, COSV65666677, COSV65674292; ClinVar: uncertain significance; called by muse, mutect2
- DCAF8 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.421); catalogued as COSV100470987; called by muse, mutect2, varscan2
- FAT4 | c.10799G>A p.G3600E | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58678321; called by muse, mutect2, varscan2
- GABRR3 | c.1144G>C p.A382P | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.943); catalogued as rs1191172932; called by muse, mutect2, varscan2
- GPKOW | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.709); catalogued as COSV99030486; called by muse, mutect2, varscan2
- HCN1 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV100299660; called by muse, mutect2
- HRH4 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV56928021; called by muse, mutect2, varscan2
- JMY | c.358C>G p.R120G | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs1429274221; called by muse, mutect2, varscan2
- KCNQ2 | c.1784G>C p.R595P (on ENST00000359125 / NM_172107.4; = p.R567P on NM_004518.6) | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.932); catalogued as COSV100610589, COSV60543634; called by muse, mutect2, varscan2
- LAMC1 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV51135892; called by muse, mutect2
- MINAR1 | c.2641G>A p.E881K | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100549058; called by muse, mutect2
- MYPOP | c.1156G>A p.G386S | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as rs920200162; called by muse, mutect2
- PCM1 | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 19/396 reads (5%) | catalogued as rs1183265581; called by muse, mutect2
- POLR3D | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs752517635; called by muse, mutect2, varscan2
- PTGDR | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.041); catalogued as COSV60093494; called by muse, mutect2
- RNF180 | c.1567C>T p.H523Y | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.139); catalogued as COSV66632738; called by muse, mutect2
- RUNX1 | c.442C>G p.L148V (on ENST00000344691 / NM_001001890.3; = p.L175V on NM_001754.5) | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs868726626; called by muse, mutect2
- SLC26A8 | c.2228G>C p.R743T | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1289350936; called by muse, mutect2, varscan2
- SLC36A4 | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV58395751; called by muse, mutect2
- SOX9 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55421793; called by muse, mutect2
- SP1 | c.514C>T p.Q172* (on ENST00000327443 / NM_138473.3; = p.Q165* on NM_003109.1) | Nonsense Mutation (SNP) | VAF 5/60 reads (8%) | catalogued as COSV59402551; called by muse, mutect2
- SPTBN2 | c.5827G>A p.D1943N | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV59446548; called by muse, mutect2
- ZFAT | c.2407G>A p.D803N | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as rs1162408610, COSV100914924; called by muse, mutect2, varscan2
- ANAPC4 | c.1284G>A p.M428I | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); called by muse, mutect2
- ARFGAP1 | c.1071G>C p.E357D | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGEF10 | c.2845G>C p.E949Q (on ENST00000398564; = p.E924Q on NM_014629.4) | Missense Mutation (SNP) | VAF 7/201 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- CEMIP2 | c.529C>T p.H177Y | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.173); called by muse, mutect2
- CIITA | c.945G>C p.K315N | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.098); called by muse, mutect2
- CTAGE1 | c.679C>G p.L227V | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- EDRF1 | c.2068C>T p.L690F (on ENST00000356792 / NM_001202438.2; = p.L656F on NM_015608.2) | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2
- FAM200A | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- FAM200B | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.119); called by muse, mutect2
- FAT4 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- FIP1L1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HSPA12A | c.834G>T p.Q278H | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.021); called by muse, mutect2
- HUWE1 | c.13051G>A p.E4351K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- IL17RA | c.2212G>C p.D738H | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.459); called by muse, mutect2
- ITIH1 | c.1925-3C>T | Splice Region (SNP) | VAF 19/244 reads (8%) | called by muse, mutect2
- KCNC4 | c.1786del p.D596Tfs*121 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | called by pindel, varscan2
- KRT39 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 13/223 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2
- LCK | c.1084C>G p.H362D | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); called by muse, mutect2
- LGALS8 | c.345+4G>A | Splice Region (SNP) | VAF 9/172 reads (5%) | called by muse, mutect2
- LRR1 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 11/192 reads (6%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); called by muse, mutect2
- MUC16 | c.10552C>G p.Q3518E | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.096); called by muse, mutect2
- NCKAP5 | c.1580C>T p.S527L | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.51); called by muse, mutect2
- NFIL3 | c.803C>G p.S268C | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- OR4P4 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.168); called by muse, mutect2
- PHF20L1 | c.1559G>C p.R520T | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2
- POLR1C | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- PRKAG2 | c.1134C>G p.I378M | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- RALGDS | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- RNF115 | c.889C>T p.Q297* | Nonsense Mutation (SNP) | VAF 10/292 reads (3%) | called by muse, mutect2
- SDHAF4 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2
- SLC12A2 | c.3436-3C>T | Splice Region (SNP) | VAF 7/126 reads (6%) | called by muse, mutect2
- SLC35E1 | c.351C>A p.F117L | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.424); called by muse, mutect2
- SLC44A3 | c.1804G>A p.E602K (on ENST00000271227 / NM_001114106.3; = p.E554K on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- STARD9 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.229); called by muse, mutect2
- SYCP2 | c.2449G>A p.D817N | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.022); called by muse, mutect2
- TBX3 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- TMEM131L | c.3538G>C p.E1180Q | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.115); called by muse, mutect2
- TOMM20L | c.143G>C p.R48T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); called by muse, mutect2
- UNC13A | c.1295G>C p.R432T | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.01); called by muse, mutect2
- WNT8A | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF599 | c.1599A>C p.K533N | Missense Mutation (SNP) | VAF 12/237 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.231); called by muse, mutect2
- ABCB10 | c.1857C>T p.F619= | Silent (SNP) | VAF 8/174 reads (5%) | catalogued as COSV60620709, COSV60624481; called by muse, mutect2
- ACOXL | c.897C>T p.F299= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as rs529004792; called by muse, mutect2
- ACSL6 | c.1134C>T p.F378= (on ENST00000379240; = p.F403= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as rs956114734; called by muse, mutect2
- ALDH1B1 | c.483C>T p.I161= | Silent (SNP) | VAF 35/229 reads (15%) | catalogued as rs753653089; called by muse, mutect2, varscan2
- AP1B1 | c.789G>A p.L263= | Silent (SNP) | VAF 12/190 reads (6%) | called by muse, mutect2
- ARAP3 | c.2622G>C p.L874= | Silent (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- ATP5MGL | c.159G>A p.L53= | Silent (SNP) | VAF 12/123 reads (10%) | called by muse, mutect2, varscan2
- BCAM | c.1527G>A p.L509= | Silent (SNP) | VAF 16/172 reads (9%) | called by muse, mutect2
- CDKN1A | c.75G>A p.V25= | Silent (SNP) | VAF 7/122 reads (6%) | called by muse, mutect2
- CFAP251 | c.456G>C p.L152= | Silent (SNP) | VAF 34/165 reads (21%) | called by muse, mutect2, varscan2
- CFTR | c.3348C>T p.F1116= | Silent (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- COG1 | c.2604G>A p.L868= | Silent (SNP) | VAF 15/160 reads (9%) | called by muse, mutect2
- ERVMER34-1 | c.1404G>A p.L468= | Silent (SNP) | VAF 25/250 reads (10%) | called by muse, mutect2, varscan2
- FBXL7 | c.351C>T p.L117= | Silent (SNP) | VAF 13/137 reads (9%) | catalogued as COSV61644884; called by muse, mutect2, varscan2
- GIMAP8 | c.1698G>A p.R566= | Silent (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- GPR35 | c.489C>T p.F163= | Silent (SNP) | VAF 9/94 reads (10%) | called by muse, mutect2, varscan2
- HSP90AB1 | c.249C>G p.T83= | Silent (SNP) | VAF 28/225 reads (12%) | called by muse, mutect2, varscan2
- IGDCC4 | c.3723G>A p.L1241= | Silent (SNP) | VAF 7/83 reads (8%) | called by muse, mutect2
- IQCC | c.957C>T p.I319= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as rs764954029; called by muse, mutect2
- LYNX1 | c.304C>T p.L102= | Silent (SNP) | VAF 5/92 reads (5%) | catalogued as COSV100235857; called by muse, mutect2
- MAGEA12 | c.447G>A p.V149= | Silent (SNP) | VAF 7/152 reads (5%) | called by muse, mutect2
- OBSL1 | c.2535G>A p.Q845= | Silent (SNP) | VAF 12/232 reads (5%) | called by muse, mutect2
- PRR5L | c.15C>T p.F5= | Silent (SNP) | VAF 7/170 reads (4%) | catalogued as rs1041921488; called by muse, mutect2
- PRSS23 | c.432C>T p.F144= | Silent (SNP) | VAF 24/326 reads (7%) | called by muse, mutect2
- PTPN5 | c.1098G>A p.E366= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs761781592; called by muse, mutect2, varscan2
- SLC18A2 | c.498C>T p.F166= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as rs1371998089; called by muse, mutect2, varscan2
- SLC5A9 | c.1992C>T p.I664= | Silent (SNP) | VAF 6/149 reads (4%) | called by muse, mutect2
- SNX5 | c.1185G>A p.Q395= | Silent (SNP) | VAF 9/112 reads (8%) | called by muse, mutect2
- SRR | c.132C>T p.F44= | Silent (SNP) | VAF 10/195 reads (5%) | called by muse, mutect2
- STAG2 | c.354C>T p.I118= | Silent (SNP) | VAF 13/190 reads (7%) | catalogued as COSV54353949, COSV54358271; called by muse, mutect2
- TRIM69 | c.1422G>A p.E474= (on ENST00000329464 / NM_182985.5; = p.E315= on NM_080745.5) | Silent (SNP) | VAF 13/351 reads (4%) | catalogued as COSV57803452; called by muse, mutect2
- TUFM | c.36G>A p.A12= | Silent (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2, varscan2
- WSB1 | c.441G>A p.L147= | Silent (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- ABLIM1 | chr10:114434234 C>G | 3'Flank (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2, varscan2
- ADGRL1 | c.3309+101C>G | Intron (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- AKNA | c.*2333C>T | 3'UTR (SNP) | VAF 11/260 reads (4%) | called by muse, mutect2
- AMT | c.258+109C>T | Intron (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- ANPEP | c.-223-69C>T | Intron (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- AP2A2 | c.*116C>T | 3'UTR (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
- ARHGAP20 | c.*1702C>T | 3'UTR (SNP) | VAF 12/121 reads (10%) | called by muse, mutect2, varscan2
- ARSB | c.*1170G>A | 3'UTR (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- ATP6V0A2 | c.*2838C>T | 3'UTR (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- BEST1 | c.1739+497G>A | Intron (SNP) | VAF 7/84 reads (8%) | catalogued as COSV56444497; called by muse, mutect2
- CCDC134 | c.*370C>T | 3'UTR (SNP) | VAF 3/43 reads (7%) | catalogued as rs1269559712; called by muse, mutect2
- CETN3 | c.*1511G>C | 3'UTR (SNP) | VAF 19/124 reads (15%) | called by muse, mutect2, varscan2
- CHODL | c.*878C>T | 3'UTR (SNP) | VAF 22/101 reads (22%) | called by muse, mutect2, varscan2
- CLSTN3 | c.*219G>T | 3'UTR (SNP) | VAF 11/104 reads (11%) | called by muse, mutect2, varscan2
- COA7 | c.*486G>A | 3'UTR (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- CTSA | c.778-146C>G | Intron (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2
- CUL4A | chr13:113208790 G>A | 5'Flank (SNP) | VAF 5/8 reads (63%) | catalogued as rs1023072270; called by muse, mutect2, varscan2
- CXCL5 | c.-67C>T | 5'UTR (SNP) | VAF 14/99 reads (14%) | called by muse, mutect2, varscan2
- DKKL1 | c.*38C>T | 3'UTR (SNP) | VAF 10/98 reads (10%) | called by muse, mutect2
- DMAC1 | c.*491C>T | 3'UTR (SNP) | VAF 10/164 reads (6%) | catalogued as rs1260142482, COSV64065758; called by muse, mutect2
- DNMT3A | c.*308C>T | 3'UTR (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- DNMT3A | c.448+243C>T | Intron (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- EIF4G3 | c.3720+1572G>T | Intron (SNP) | VAF 15/209 reads (7%) | catalogued as rs761646145; called by muse, mutect2
- ELP4 | c.1039+21G>A | Intron (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2
- ELP4 | chr11:31785906 C>T | 3'Flank (SNP) | VAF 7/102 reads (7%) | called by muse, mutect2
- ERC1 | c.*1002G>A | 3'UTR (SNP) | VAF 7/120 reads (6%) | catalogued as rs1259626467; called by muse, mutect2
- ETV1 | chr7:13892574 G>A | 3'Flank (SNP) | VAF 9/34 reads (26%) | catalogued as rs1288759743; called by muse, mutect2, varscan2
- FAM120C | c.*1926G>A | 3'UTR (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- FAM200B | c.-444G>A | 5'UTR (SNP) | VAF 6/67 reads (9%) | called by muse, mutect2
- FER | c.*7984C>T | 3'UTR (SNP) | VAF 7/73 reads (10%) | called by muse, mutect2
- FLJ42393 | n.929C>T | RNA (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- GRIK4 | chr11:120988177 G>A | 3'Flank (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- GRIN2B | c.*626G>A | 3'UTR (SNP) | VAF 16/160 reads (10%) | called by muse, mutect2
- HHIP | c.*6178G>A | 3'UTR (SNP) | VAF 23/185 reads (12%) | called by muse, mutect2, varscan2
- HIF1AN | c.*1425C>T | 3'UTR (SNP) | VAF 14/131 reads (11%) | called by muse, mutect2, varscan2
- HSD17B12 | c.283+820G>C | Intron (SNP) | VAF 24/342 reads (7%) | called by muse, mutect2
- IL24 | c.*17C>T | 3'UTR (SNP) | VAF 6/107 reads (6%) | catalogued as rs1237204843; called by muse, mutect2
- INHBE | chr12:57454777 C>T | 5'Flank (SNP) | VAF 10/117 reads (9%) | catalogued as rs1414365315; called by muse, mutect2
- IRF2BPL | c.-136C>T | 5'UTR (SNP) | VAF 5/36 reads (14%) | catalogued as rs1429734957; called by muse, mutect2, varscan2
- JMJD4 | c.*237G>T | 3'UTR (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- KAT8 | c.1312+141C>T | Intron (SNP) | VAF 7/87 reads (8%) | catalogued as rs1168081224; called by muse, mutect2
- KIF3B | c.*2700G>A | 3'UTR (SNP) | VAF 9/107 reads (8%) | called by muse, mutect2
- LIPC | c.1388+2358C>G | Intron (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- MCMDC2 | c.1073+57C>T | Intron (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- MELTF | c.*877C>A | 3'UTR (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- MXRA8 | chr1:1361607 C>G | 5'Flank (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- OPN4 | c.*64C>G | 3'UTR (SNP) | VAF 18/234 reads (8%) | called by muse, mutect2
- OR4H12P | n.321G>C | RNA (SNP) | VAF 13/191 reads (7%) | called by muse, mutect2
- PCGF5 | c.*5896C>T | 3'UTR (SNP) | VAF 24/125 reads (19%) | called by muse, mutect2, varscan2
- PDS5A | c.*1225A>G | 3'UTR (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- PHF20L1 | c.1579+229G>C | Intron (SNP) | VAF 13/116 reads (11%) | called by muse, mutect2, varscan2
- PPIG | c.*1524G>A | 3'UTR (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2, varscan2
- PPIG | c.*2248G>T | 3'UTR (SNP) | VAF 20/129 reads (16%) | called by muse, mutect2, varscan2
- PPP1R12B | c.*6909G>A | 3'UTR (SNP) | VAF 12/160 reads (8%) | called by muse, mutect2
- PRMT9 | c.*474G>A | 3'UTR (SNP) | VAF 16/149 reads (11%) | called by muse, mutect2, varscan2
- PTP4A1 | c.*959G>A | 3'UTR (SNP) | VAF 6/116 reads (5%) | called by muse, mutect2
- PTP4A2 | c.-318C>T | 5'UTR (SNP) | VAF 32/180 reads (18%) | called by muse, mutect2, varscan2
- RALA | c.498+582C>T | Intron (SNP) | VAF 10/38 reads (26%) | catalogued as rs898591982; called by muse, mutect2, varscan2
- RFTN1 | c.827-101C>G | Intron (SNP) | VAF 4/20 reads (20%) | called by muse, varscan2
- RNFT1 | c.*81C>A | 3'UTR (SNP) | VAF 33/187 reads (18%) | catalogued as COSV99847238; called by muse, mutect2, varscan2
- ROBO1 | c.88+56765C>T | Intron (SNP) | VAF 9/63 reads (14%) | catalogued as rs542421142; called by muse, mutect2, varscan2
- RTN1 | c.2182+42C>G | Intron (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- SCAMP2 | c.*254C>T | 3'UTR (SNP) | VAF 4/98 reads (4%) | called by muse, mutect2
- SERPINB8 | c.721-444C>T | Intron (SNP) | VAF 47/186 reads (25%) | called by muse, mutect2, varscan2
- SLC11A2 | c.*1886C>T | 3'UTR (SNP) | VAF 3/27 reads (11%) | catalogued as rs1258348035; called by muse, mutect2
- SLC12A2 | c.*2032G>A | 3'UTR (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- SLC52A2 | c.-107G>A | 5'UTR (SNP) | VAF 9/101 reads (9%) | called by muse, mutect2
- SNX13 | c.2626+1140C>T | Intron (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- SPINK2 | c.*156G>A | 3'UTR (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- SPOPL | c.*1080G>A | 3'UTR (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2
- SREBF1 | c.*780C>T | 3'UTR (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- SSPOP | n.9048C>T | RNA (SNP) | VAF 11/84 reads (13%) | catalogued as rs751664053, COSV100948253; called by muse, mutect2, varscan2
- THBD | c.*1808C>T | 3'UTR (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- TMEM131 | c.5109-139C>G | Intron (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- TMEM250 | c.*1342C>G | 3'UTR (SNP) | VAF 7/109 reads (6%) | called by muse, mutect2
- TNFRSF12A | c.*300G>C | 3'UTR (SNP) | VAF 4/37 reads (11%) | catalogued as rs1044326; called by mutect2, varscan2
- TPRXL | n.2214G>C | RNA (SNP) | VAF 9/98 reads (9%) | called by muse, mutect2
- TRAF1 | c.*34G>C | 3'UTR (SNP) | VAF 8/102 reads (8%) | catalogued as COSV100875107; called by muse, mutect2
- TRIB3 | c.*404C>T | 3'UTR (SNP) | VAF 19/47 reads (40%) | called by muse, mutect2, varscan2
- UPB1 | c.-54C>T | 5'UTR (SNP) | VAF 9/83 reads (11%) | catalogued as rs753442714, COSV58112485; called by muse, mutect2
- USP31 | c.*4224C>A | 3'UTR (SNP) | VAF 10/111 reads (9%) | called by muse, mutect2
- ZNF24 | c.*2650C>T | 3'UTR (SNP) | VAF 7/97 reads (7%) | called by muse, mutect2
- ZNF496 | c.*1203C>T | 3'UTR (SNP) | VAF 11/89 reads (12%) | called by muse, mutect2, varscan2
- ZNF587 | c.*4227C>T | 3'UTR (SNP) | VAF 4/85 reads (5%) | called by muse, mutect2
- ZNF662 | c.*431C>T | 3'UTR (SNP) | VAF 11/115 reads (10%) | called by muse, mutect2
- ZNF681 | c.*564G>A | 3'UTR (SNP) | VAF 13/145 reads (9%) | called by muse, mutect2
- ZNF791 | c.*142C>T | 3'UTR (SNP) | VAF 4/89 reads (4%) | called by muse, mutect2
